Somatic mutation profile of tumor specimen 0DIFJM from CCDI case PBBVSE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 15.6 years (5,686 days).
Specimen 0DIFJM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bcbddd0-b890-4579-9318-d46d5214e2ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIFIK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e13bdd01-a714-4401-9fa0-4d801de3f9a8

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 1, Splice Region 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1649T>A p.V550E | Missense Mutation (SNP) | VAF 302/612 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519793; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 110/356 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- CASKIN1 | c.3566C>T p.P1189L | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs768810515; called by muse, mutect2, varscan2
- FAM13B | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 64/710 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371205351; called by muse, mutect2
- HCN1 | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 136/596 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV57502518; called by mutect2, varscan2
- IRAK3 | c.1149G>A p.L383= | Splice Region (SNP) | VAF 111/557 reads (20%) | catalogued as rs377627173; called by muse, mutect2, varscan2
- KCNH5 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 170/560 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762196737, COSV59781148; called by muse, mutect2, varscan2
- MUC17 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV60295411, COSV60300184; called by muse, mutect2, varscan2
- ARHGEF18 | c.3143T>C p.L1048P (on ENST00000359920 / NM_001130955.2; = p.L944P on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, varscan2
- ATP4A | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf50 | c.432G>T p.K144N (on ENST00000324058; = p.K1376N on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 223/659 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CTTNBP2 | c.1289C>A p.S430* | Nonsense Mutation (SNP) | VAF 102/467 reads (22%) | called by muse, mutect2, varscan2
- LRRC34 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 30/854 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2
- MDH1B | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 115/512 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GREB1L | c.4735+36_4735+37del | Intron (DEL) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100360835; called by muse, varscan2
